Gene-level copy-number profile of tumor specimen TCGA-W7-A93O-01A from TCGA case TCGA-W7-A93O, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen TCGA-W7-A93O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e822e61f-a709-4de1-aac2-5a9ab2a680e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-W7-A93O-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/90dadd0c-f5f1-4b9d-857b-677dc95f4813

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 474; copy number 2: 26,258; copy number 3: 13,579; copy number 4: 12,910; copy number 5: 4,461; copy number 6: 525; copy number 8: 26; copy number 11: 25; copy number 12: 13; copy number 13: 2; copy number 76: 33; copy number 260: 11.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr9:21,967,752–22,214,672, 8 genes (within-gene range 0–2): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr15:20,803,505–20,866,314, 6 genes: AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:20,916,686–21,058,440, 5 genes (within-gene range 0–3): NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.
- chr15:30,083,053–30,513,698, 26 genes: GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3.
- chr15:30,540,093–30,545,969, 1 gene: AC026150.1.
- chr22:18,400,407–18,719,341, 17 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,096 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:586,071–827,796, 1 gene, copy number 5 (within-gene range 2–5): AL669831.3.
- chr1:629,062–12,512,047, 381 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:45,016,399–46,570,255, 50 genes, copy number 6 (within-gene range 2–6): ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN.
- chr1:147,629,652–148,519,604, 44 genes, copy number 5: ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G.
- chr1:149,676,851–150,629,612, 53 genes, copy number 6 (within-gene range 3–6): AC243772.3, RNU1-68P, AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr1:151,402,724–152,196,699, 45 genes, copy number 5 (within-gene range 4–5): POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:155,745,829–157,237,136, 77 genes, copy number 5 (broad region; genes not listed).
- chr1:157,629,939–157,949,071, 11 genes, copy number 5: AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1.
- chr1:159,998,651–162,370,475, 105 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:162,342,546–162,342,640, 1 gene, copy number 6 (within-gene range 4–6): MIR556.
- chr3:130,048,143–130,055,920, 1 gene, copy number 8: AC083906.4.
- chr3:169,709,295–170,181,749, 25 genes, copy number 8: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr7:62,275,361–68,119,209, 200 genes, copy number 5 (broad region; genes not listed).
- chr7:72,558,744–96,859,618, 390 genes, copy number 5 (broad region; genes not listed).
- chr7:97,117,698–128,092,609, 538 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:127,997,597–159,233,377, 739 genes, copy number 5 (broad region; genes not listed).
- chr8:126,325,454–128,564,679, 33 genes, copy number 76: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr10:50,676,743–52,298,423, 17 genes, copy number 11–12 (within-gene range 2–12): NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr10:120,608,580–122,826,868, 34 genes, copy number 11–260 (within-gene range 2–260): AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120, DMBT1L1.
- chr19:27,638,483–58,605,223, 1,672 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 474. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
